Somatic mutation profile of tumor specimen 0E11ZW from CCDI case PBCVEW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E11ZW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b5837ff-d636-4975-a8d1-7b510d5eaea3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E11Z8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a1eae3e-ebb7-424b-b544-15267da8616b

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 4, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NLRP4 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs147977916; called by muse, varscan2
- TTC30A | c.1948T>A p.S650T | Missense Mutation (SNP) | VAF 106/281 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV63101284; called by muse, varscan2
- DES | c.1198G>A p.V400M | Missense Mutation (SNP) | VAF 84/272 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.196); called by muse, varscan2
- JUN | c.484A>G p.S162G | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.01); called by muse, varscan2
- LARP1 | c.848C>T p.A283V (on ENST00000518297 / NM_033551.3; = p.A206V on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/178 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, varscan2
- MAP2K7 | c.1082T>C p.L361P | Missense Mutation (SNP) | VAF 78/149 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PPP1R32 | c.745C>T p.H249Y | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.179); called by muse, varscan2
- RBMXL3 | c.2419A>T p.S807C | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.7); called by muse, varscan2
- TMOD3 | c.882G>C p.R294S | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); called by muse, varscan2
- TMOD3 | c.883C>T p.Q295* | Nonsense Mutation (SNP) | VAF 18/148 reads (12%) | called by muse, varscan2
- TTN | c.62552C>T p.T20851I (on ENST00000591111; = p.T13427I on NM_003319.4) | Missense Mutation (SNP) | VAF 94/279 reads (34%) | PolyPhen benign (0); called by muse, varscan2
- CD163 | c.1935C>A p.I645= | Silent (SNP) | VAF 34/108 reads (31%) | catalogued as COSV63137122; called by muse, varscan2
- ACSM2A | c.1098+63C>A | Intron (SNP) | VAF 5/32 reads (16%) | called by muse, varscan2
- CAPN7 | c.2074-73T>C | Intron (SNP) | VAF 6/50 reads (12%) | called by muse, varscan2
- FANCM | c.5717-76A>G | Intron (SNP) | VAF 8/26 reads (31%) | called by muse, varscan2
- TFDP2 | c.187-5129C>T | Intron (SNP) | VAF 144/374 reads (39%) | called by muse, varscan2
